Somatic mutation profile of tumor specimen C3L-00026-01 (aliquot CPT0001500005) from CPTAC case C3L-00026, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 65.4 years (23,881 days).
Specimen C3L-00026-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f246a4af-7265-41f1-8087-280bb82ad324.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00026-31 (Blood Derived Normal), aliquot CPT0000130163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08501496-bae0-4bf9-b805-49b76bfcd7cd

The open-access MAF lists 168 somatic variants for this specimen: 120 protein-altering or splice-affecting, 26 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 26, Frame Shift Del 11, Intron 8, 5'Flank 6, Frame Shift Ins 5, Nonsense Mutation 4, Splice Site 3, RNA 3, 5'UTR 3, Splice Region 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.444dup p.A149Cfs*25 | Frame Shift Ins (INS) | VAF 143/393 reads (36%) | catalogued as rs869025653, COSV56544361, COSV56568596; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ALDH2 | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55670582; called by muse, mutect2, varscan2
- ANKRD11 | c.3955G>A p.A1319T | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs567938525; called by muse, mutect2, varscan2
- BTBD8 | c.1640G>T p.R547M (on ENST00000636805 / NM_001376131.1; = p.R34M on NM_015237.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64885819; called by muse, varscan2
- CCDC88C | c.5848G>A p.V1950M | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1304342453; called by muse, mutect2, varscan2
- CELSR1 | c.8497G>A p.V2833M | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs774171527; called by muse, mutect2, varscan2
- CUBN | c.9967_9968del p.W3323Gfs*62 | Frame Shift Del (DEL) | VAF 84/344 reads (24%) | catalogued as rs1445856521; called by pindel, varscan2
- DENND5B | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV99080245; called by muse, mutect2, varscan2
- FARP1 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779764921, COSV60334210; called by muse, varscan2
- GLRA1 | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 89/329 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51028852; called by muse, mutect2, varscan2
- ITIH5 | c.566T>G p.V189G | Missense Mutation (SNP) | VAF 84/287 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV56903999; called by muse, mutect2, varscan2
- LAMA2 | c.4591C>T p.P1531S | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV70356161; called by muse, mutect2, varscan2
- MYLK4 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 84/280 reads (30%) | catalogued as COSV51149937; called by muse, mutect2, varscan2
- MYZAP | c.1360A>G p.T454A (on ENST00000267853 / NM_001018100.5; = p.T426A on NM_152451.7) | Missense Mutation (SNP) | VAF 79/264 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1459075654; called by muse, mutect2, varscan2
- NEB | c.10003A>G p.M3335V | Missense Mutation (SNP) | VAF 85/374 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs768336165; called by muse, mutect2, varscan2
- PCDHB3 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 137/504 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV50565386; called by muse, mutect2, varscan2
- ROBO3 | c.963G>C p.E321D | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV67299181; called by muse, mutect2, varscan2
- SH3TC1 | c.2596G>A p.A866T | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs1002236984; called by muse, mutect2, varscan2
- SLC16A11 | c.1024C>A p.L342M (on ENST00000308009; = p.L318M on NM_153357.3) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs1337021358, COSV100338748; called by muse, mutect2, varscan2
- SLC27A4 | c.524G>C p.R175P | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100056560; called by muse, mutect2
- SLC27A4 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs1372996668, COSV55961063; called by muse, mutect2
- SMTNL1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 94/342 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as rs772298294; called by muse, mutect2, varscan2
- SVEP1 | c.9658G>T p.V3220L | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs896988278; called by muse, mutect2, varscan2
- TNKS | c.458G>A p.S153N | Missense Mutation (SNP) | VAF 104/370 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs370539656; called by muse, mutect2, varscan2
- UFSP2 | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52993183; called by muse, mutect2, varscan2
- XK | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 105/255 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.077); catalogued as COSV66120416; called by muse, mutect2, varscan2
- YTHDC2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV50748251; called by muse, mutect2
- ZNF492 | c.1159C>A p.H387N | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71762156; called by muse, mutect2, varscan2
- ZNF626 | c.982del p.T329Lfs*61 | Frame Shift Del (DEL) | VAF 66/334 reads (20%) | catalogued as COSV101656995; called by pindel, varscan2
- AASS | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 91/442 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ADCK2 | c.1801G>C p.G601R | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFM | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.617); called by muse, mutect2
- AMER1 | c.2594G>C p.G865A | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ANKRD30A | c.1001G>C p.G334A (on ENST00000611781; = p.G278A on NM_052997.2) | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANKRD34C | c.986G>A p.W329* | Nonsense Mutation (SNP) | VAF 66/173 reads (38%) | called by muse, mutect2, varscan2
- ARHGAP23 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATXN2 | c.2605C>T p.L869F (on ENST00000550104; = p.L709F on NM_002973.4) | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ATXN7L1 | c.182-1G>A p.X61_splice | Splice Site (SNP) | VAF 28/326 reads (9%) | called by muse, mutect2
- BBS5 | c.446_449del p.N149Sfs*3 | Frame Shift Del (DEL) | VAF 67/332 reads (20%) | called by mutect2, pindel, varscan2
- C11orf45 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CABIN1 | c.5147G>C p.G1716A | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK13 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHM | c.1007T>A p.I336N | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.29); called by muse, varscan2
- CHRNA4 | c.1389del p.R464Gfs*101 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- CLDN2 | c.610G>C p.A204P | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- COLEC11 | c.737T>A p.V246E | Missense Mutation (SNP) | VAF 185/604 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- COX7B2 | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUX1 | c.1739G>C p.G580A | Missense Mutation (SNP) | VAF 15/508 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DDX1 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DNAAF3 | c.1285del p.R429Gfs*5 (on ENST00000524407 / NM_001256715.2; = p.R476Gfs*5 on NM_178837.4) | Frame Shift Del (DEL) | VAF 35/144 reads (24%) | called by mutect2, pindel, varscan2
- DSCAM | c.3041del p.N1014Mfs*9 | Frame Shift Del (DEL) | VAF 44/178 reads (25%) | called by mutect2, pindel, varscan2
- DYRK4 | c.774C>G p.H258Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DYSF | c.4639-12_4648del p.X1547_splice | Splice Site (DEL) | VAF 46/206 reads (22%) | called by mutect2, pindel
- ECI2 | c.224G>C p.G75A (on ENST00000380118 / NM_206836.3; = p.G45A on NM_006117.2) | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDC4 | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- EFCC1 | c.646_653del p.D216Rfs*7 | Frame Shift Del (DEL) | VAF 43/202 reads (21%) | called by mutect2, pindel, varscan2
- EIF2AK2 | c.120G>A p.R40= | Splice Region (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2
- ERCC3 | c.1740dup p.Y581Lfs*23 | Frame Shift Ins (INS) | VAF 57/249 reads (23%) | called by pindel, varscan2
- ERCC3 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 95/345 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FLT3 | c.616_619del p.C206Kfs*23 | Frame Shift Del (DEL) | VAF 45/142 reads (32%) | called by mutect2, pindel, varscan2
- FSIP2 | c.6719A>T p.K2240I | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2
- FXYD6 | c.259+7G>C | Splice Region (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
- GCOM1 | c.940C>A p.H314N | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GLS | c.1030C>A p.L344I | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- GPR17 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HECTD4 | c.6580G>A p.A2194T | Missense Mutation (SNP) | VAF 65/235 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXA5 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- HUS1B | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- IL17C | c.493C>A p.R165S | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ITPR2 | c.5684G>A p.G1895E | Missense Mutation (SNP) | VAF 99/387 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- JRK | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- KIAA1671 | c.2884A>T p.S962C | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- LINS1 | c.98A>G p.N33S | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2
- LMO7 | c.749T>A p.I250N (on ENST00000357063; = p.I265N on NM_005358.5) | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- MGAT5 | c.1440T>A p.Y480* | Nonsense Mutation (SNP) | VAF 53/175 reads (30%) | called by muse, mutect2, varscan2
- MGST1 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- MRPL16 | c.141dup p.P48Tfs*4 | Frame Shift Ins (INS) | VAF 26/112 reads (23%) | called by mutect2, pindel
- MSANTD1 | c.790C>G p.R264G | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MXD4 | c.517A>G p.S173G | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- MYBPC1 | c.1288T>G p.L430V (on ENST00000550270 / NM_206820.2; = p.L455V on NM_002465.4) | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MYLK3 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 24/91 reads (26%) | called by muse, mutect2, varscan2
- NAV3 | c.414+2T>C p.X138_splice | Splice Site (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- NCOR2 | c.970G>C p.A324P | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- OR52N2 | c.881T>C p.V294A | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- PCDHGC4 | c.2300G>A p.G767D | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PLEKHG2 | c.3812G>A p.G1271D | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHG4B | c.1694C>G p.P565R (on ENST00000283426; = p.P921R on NM_052909.5) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- PLOD1 | c.1073A>G p.N358S | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPARA | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PPP1R9B | c.74del p.A25Gfs*6 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- PPP2R2A | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP6R2 | c.1813T>C p.F605L (on ENST00000216061 / NM_001365836.1; = p.F578L on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- PRELID1 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 123/407 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKAG3 | c.733_735del p.D245del | In Frame Del (DEL) | VAF 41/264 reads (16%) | called by mutect2, pindel, varscan2
- PRPF40B | c.1323G>A p.M441I (on ENST00000380281; = p.M435I on NM_012272.3) | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PTGDR2 | c.970del p.E324Rfs*31 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | called by mutect2, pindel, varscan2
- RAPGEF3 | c.2653T>C p.C885R (on ENST00000389212; = p.C843R on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- RASA1 | c.1207_1208del p.P403Nfs*14 | Frame Shift Del (DEL) | VAF 62/255 reads (24%) | called by mutect2, pindel, varscan2
- RELN | c.7127C>T p.S2376F | Missense Mutation (SNP) | VAF 241/524 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFX1 | c.1558C>A p.L520M | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- RPS6KC1 | c.1363A>T p.S455C | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SH3BP2 | c.1355C>G p.P452R | Missense Mutation (SNP) | VAF 116/329 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SLC12A6 | c.713T>C p.M238T (on ENST00000354181 / NM_001365088.1; = p.M187T on NM_005135.2) | Missense Mutation (SNP) | VAF 123/371 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SLC25A17 | c.143C>A p.T48K | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- SLC35B1 | c.506T>C p.L169S (on ENST00000649906; = p.L132S on NM_005827.4) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SLC45A4 | c.2048G>T p.G683V (on ENST00000517878 / NM_001286646.2; = p.G632V on NM_001080431.2) | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A2 | c.899G>C p.R300P | Missense Mutation (SNP) | VAF 73/351 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLIT1 | c.4180C>A p.L1394I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SNX18 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUPT5H | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TAF4B | c.1530G>C p.Q510H | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TBKBP1 | c.428A>T p.D143V | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- TCF20 | c.1417A>C p.M473L | Missense Mutation (SNP) | VAF 84/294 reads (29%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TRIO | c.8191C>A p.H2731N | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- TSR1 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, varscan2
- TTC7A | c.2369G>A p.S790N | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UBXN6 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- USF3 | c.320_321dup p.E108Lfs*4 | Frame Shift Ins (INS) | VAF 28/112 reads (25%) | called by mutect2, pindel, varscan2
- VAMP1 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, varscan2
- VPS13D | c.5797dup p.Y1933Lfs*10 | Frame Shift Ins (INS) | VAF 47/218 reads (22%) | called by mutect2, pindel, varscan2
- ASTN1 | c.3414C>T p.D1138= | Silent (SNP) | VAF 58/181 reads (32%) | catalogued as rs754147184, COSV62500061; called by muse, mutect2, varscan2
- CAMSAP2 | c.4437A>G p.V1479= (on ENST00000236925 / NM_001297707.2; = p.V1468= on NM_203459.3) | Silent (SNP) | VAF 26/92 reads (28%) | called by muse, varscan2
- CAMSAP3 | c.2070G>A p.P690= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as rs999228829; called by muse, mutect2, varscan2
- COL18A1 | c.165G>A p.Q55= | Silent (SNP) | VAF 59/191 reads (31%) | called by muse, mutect2, varscan2
- CRNKL1 | c.990G>A p.R330= | Silent (SNP) | VAF 28/154 reads (18%) | catalogued as rs748786848; called by muse, mutect2, varscan2
- DCUN1D1 | c.18A>G p.S6= | Silent (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- EFHC2 | c.900T>C p.D300= | Silent (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- FAM160A1 | c.3045G>A p.K1015= | Silent (SNP) | VAF 44/190 reads (23%) | called by muse, mutect2, varscan2
- FCGBP | c.4032C>T p.N1344= | Silent (SNP) | VAF 48/612 reads (8%) | catalogued as rs1192326618; called by muse, mutect2
- GLB1L3 | c.276C>A p.G92= | Silent (SNP) | VAF 20/201 reads (10%) | catalogued as COSV66281120; called by muse, mutect2, varscan2
- GPN3 | c.402C>A p.V134= | Silent (SNP) | VAF 44/135 reads (33%) | called by muse, mutect2, varscan2
- MAML2 | c.2823C>T p.T941= | Silent (SNP) | VAF 8/181 reads (4%) | called by muse, mutect2
- MYO15A | c.4173G>A p.Q1391= | Silent (SNP) | VAF 37/408 reads (9%) | catalogued as rs759870345; called by muse, mutect2
- NOC2L | c.195T>A p.R65= | Silent (SNP) | VAF 40/129 reads (31%) | called by muse, mutect2, varscan2
- NPC1L1 | c.3057G>A p.R1019= | Silent (SNP) | VAF 62/700 reads (9%) | catalogued as rs142671854; called by muse, mutect2
- PELI2 | c.192G>A p.T64= | Silent (SNP) | VAF 43/183 reads (23%) | catalogued as rs774793723, COSV50713364; called by muse, mutect2, varscan2
- PLD1 | c.2046C>T p.A682= | Silent (SNP) | VAF 39/213 reads (18%) | catalogued as rs1416841541; called by muse, mutect2, varscan2
- SFTA2 | c.156C>T p.C52= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs1372879962; called by muse, mutect2, varscan2
- SLC28A1 | c.1308G>A p.L436= | Silent (SNP) | VAF 117/387 reads (30%) | called by muse, mutect2, varscan2
- SPG11 | c.5364G>A p.V1788= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- STXBP3 | c.384G>A p.K128= | Silent (SNP) | VAF 32/147 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.58191C>G p.V19397= (on ENST00000591111; = p.V11973= on NM_003319.4) | Silent (SNP) | VAF 15/56 reads (27%) | called by mutect2, varscan2
- UBALD1 | c.339T>C p.H113= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2
- USP43 | c.2286G>A p.Q762= | Silent (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- ZNF281 | c.759C>T p.I253= | Silent (SNP) | VAF 84/239 reads (35%) | catalogued as rs756988570; called by muse, mutect2, varscan2
- ZNF865 | c.1602G>A p.G534= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- AC099548.2 | n.1511G>A | RNA (SNP) | VAF 149/1177 reads (13%) | catalogued as rs761579658; called by muse, mutect2, varscan2
- AFDN | c.2038-759G>A | Intron (SNP) | VAF 50/132 reads (38%) | catalogued as COSV60051962; called by muse, mutect2, varscan2
- BCS1L | c.320+32G>T | Intron (SNP) | VAF 134/617 reads (22%) | called by mutect2, varscan2
- CADM2 | c.62-75525C>T | Intron (SNP) | VAF 32/164 reads (20%) | catalogued as rs889027373; called by muse, mutect2, varscan2
- HCG27 | n.123+318G>A | Intron (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- HDGF | chr1:156752242 G>A | 5'Flank (SNP) | VAF 66/193 reads (34%) | called by muse, mutect2, varscan2
- LIF | c.-47G>A | 5'UTR (SNP) | VAF 116/372 reads (31%) | catalogued as COSV50776552; called by muse, mutect2, varscan2
- LINC00470 | n.1756C>A | RNA (SNP) | VAF 6/129 reads (5%) | called by muse, mutect2
- METTL26 | c.361-16T>A | Intron (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- PPP2R2C | c.71-64T>A | Intron (SNP) | VAF 58/227 reads (26%) | called by muse, mutect2
- RAX2 | c.*51C>T | 3'UTR (SNP) | VAF 20/80 reads (25%) | catalogued as rs1291917539; called by muse, varscan2
- RHCG | c.371+490G>T | Intron (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- RNF32 | chr7:156640528 G>T | 5'Flank (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- RPL10 | c.-107C>T | 5'UTR (SNP) | VAF 142/330 reads (43%) | catalogued as rs782378623; called by muse, mutect2, varscan2
- SSPOP | n.4736C>T | RNA (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- THAP7 | chr22:21002732 G>A | 5'Flank (SNP) | VAF 25/79 reads (32%) | catalogued as rs923060042; called by muse, mutect2, varscan2
- TMEM70 | c.-77C>T | 5'UTR (SNP) | VAF 48/132 reads (36%) | catalogued as rs1265302004; called by muse, varscan2
- USP22 | chr17:21043695 C>T | 5'Flank (SNP) | VAF 33/68 reads (49%) | catalogued as rs968474274; called by muse, mutect2, varscan2
- XBP1 | c.*110dup | 3'UTR (INS) | VAF 27/101 reads (27%) | called by mutect2, pindel, varscan2
- ZNF205 | chr16:3112399 C>G | 5'Flank (SNP) | VAF 39/142 reads (27%) | called by muse, mutect2, varscan2
- ZNF267 | c.3+1272G>A | Intron (SNP) | VAF 76/342 reads (22%) | called by muse, varscan2
- ZNF48 | chr16:30395274 C>G | 5'Flank (SNP) | VAF 43/239 reads (18%) | called by muse, mutect2, varscan2
